Somatic mutation profile of tumor specimen TCGA-XF-A9T0-01A (aliquot TCGA-XF-A9T0-01A-11D-A391-08) from TCGA case TCGA-XF-A9T0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.0 years (25,190 days).
Specimen TCGA-XF-A9T0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5688cdb1-f2bc-47ca-a3c4-c53a69308e5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9T0-10A (Blood Derived Normal), aliquot TCGA-XF-A9T0-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d907b2aa-7682-41a8-8fac-26515746926e

The open-access MAF lists 939 somatic variants for this specimen: 659 protein-altering or splice-affecting, 258 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 556, Silent 258, Nonsense Mutation 54, Frame Shift Del 18, Splice Site 14, Intron 9, In Frame Del 8, Splice Region 7, RNA 4, 5'Flank 3, 3'UTR 3, Frame Shift Ins 1.

Variants (750 of 939; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.1816G>C p.E606Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101228885, COSV67268042; called by muse, mutect2, varscan2
- KRIT1 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 56/71 reads (79%) | catalogued as rs1563263366, CM014938, COSV100388883; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.2639+1G>A p.X880_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as rs746752313, COSV55557161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 35/51 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TBX1 | c.582C>G p.H194Q | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs74315522, CM071113, COSV60354909; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 43/48 reads (90%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ABCA5 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV67018345; called by muse, mutect2, varscan2
- ABCC4 | c.1706T>A p.V569D | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65316650; called by muse, mutect2, varscan2
- ACTG1 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59510417; called by muse, mutect2, varscan2
- ACTRT3 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as rs751370499, COSV57754992; called by muse, mutect2, varscan2
- ADAM10 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.042); catalogued as COSV53053739; called by muse, mutect2, varscan2
- ADAMTS1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as COSV53172305; called by muse, mutect2, varscan2
- ADAMTS9 | c.4676G>T p.W1559L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1402481542, COSV55787332; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1241A>G p.H414R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV57861149; called by muse, mutect2
- ADGRF3 | c.418G>A p.E140K (on ENST00000311519 / NM_001145168.1; = p.E81K on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.025); catalogued as rs771369065, COSV61052210; called by muse, mutect2, varscan2
- ADGRF5 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV51938196; called by muse, mutect2, varscan2
- ADH5 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779296852, COSV56448747; called by muse, mutect2, varscan2
- AEBP1 | c.2494G>A p.G832R | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT tolerated (0.46); PolyPhen benign (0.153); catalogued as COSV56258733; called by muse, mutect2, varscan2
- AGA | c.863A>C p.K288T | Missense Mutation (SNP) | VAF 78/103 reads (76%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV52807252; called by muse, mutect2, varscan2
- AGAP3 | c.505G>A p.E169K (on ENST00000622464; = p.E205K on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/151 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV58995905; called by muse, mutect2, varscan2
- AGL | c.4277G>T p.G1426V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1279823808, COSV54056477; called by muse, mutect2, varscan2
- AGO4 | c.1472A>G p.D491G | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV64618162; called by muse, mutect2, varscan2
- AKNA | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56314249; called by muse, mutect2, varscan2
- ALDH16A1 | c.2042T>G p.L681R | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53195788; called by muse, mutect2, varscan2
- ALDH3A1 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); catalogued as rs1334386468, COSV56736377; called by muse, mutect2, varscan2
- ALMS1 | c.10165G>A p.E3389K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52517844; called by muse, mutect2, varscan2
- ANAPC1 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs551412961, COSV61978367; called by muse, mutect2, varscan2
- ANK2 | c.7247G>A p.R2416Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.222); catalogued as rs766001488, COSV52179302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKAR | c.3671C>T p.S1224L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55616221; called by muse, mutect2, varscan2
- ANKRD26 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.162); catalogued as rs1211178906, COSV101063333; called by muse, mutect2, varscan2
- ANKRD27 | c.2977C>T p.H993Y | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV60134641; called by muse, mutect2, varscan2
- ANKRD40 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53334552; called by muse, mutect2, varscan2
- ANO1 | c.2093A>G p.Q698R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV60287798; called by muse, mutect2, varscan2
- AP5B1 | c.1649G>A p.G550E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.64); PolyPhen benign (0.279); catalogued as COSV57503693; called by muse, mutect2, varscan2
- AQR | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV50044943; called by muse, mutect2, varscan2
- ARHGAP31 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 32/59 reads (54%) | catalogued as COSV99957512; called by muse, mutect2, varscan2
- ARHGEF1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV61529097; called by muse, mutect2, varscan2
- ARID1A | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV61378814, COSV61384930; called by muse, mutect2, varscan2
- ARVCF | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 255/314 reads (81%) | SIFT tolerated (0.69); PolyPhen benign (0.018); catalogued as rs768589776, COSV54269016; called by muse, mutect2, varscan2
- ASTL | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs973673037, COSV60903683; called by muse, mutect2, varscan2
- ASXL3 | c.3169A>T p.I1057F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52474779; called by mutect2, varscan2
- ATAD2 | c.2719-1G>T p.X907_splice | Splice Site (SNP) | VAF 17/124 reads (14%) | catalogued as rs1348662867, COSV54884981; called by muse, mutect2, varscan2
- ATAD2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1441426607, COSV54884990; called by muse, mutect2, varscan2
- ATAD5 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV58977063; called by muse, mutect2, varscan2
- ATP2B1 | c.1739C>T p.S580F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53811291; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV67778650; called by muse, mutect2, varscan2
- ATXN2L | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs776614927, COSV57366960; called by muse, mutect2, varscan2
- AVL9 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 188/239 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59468097; called by muse, mutect2, varscan2
- BAP1 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56231252, COSV56238617; called by muse, mutect2, varscan2
- BAP1 | c.1891G>T p.E631* | Nonsense Mutation (SNP) | VAF 27/49 reads (55%) | catalogued as COSV56235325, COSV56238458; called by muse, mutect2, varscan2
- BARHL1 | c.392_409del p.A131_F137delinsV | In Frame Del (DEL) | VAF 10/29 reads (34%) | catalogued as COSV55038586; called by mutect2, varscan2
- BCDIN3D | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV61702731; called by muse, mutect2, varscan2
- BCL2L12 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55864229, COSV55864633; called by muse, mutect2, varscan2
- BCL9 | c.2432A>G p.N811S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1553205108, COSV52348483; called by muse, mutect2, varscan2
- BCO2 | c.359C>G p.T120R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV63064433; called by muse, mutect2, varscan2
- BIK | c.446C>G p.P149R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99295584, COSV99295748; called by muse, mutect2
- BLNK | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99814120; called by muse, mutect2, varscan2
- BLOC1S2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as COSV58397940; called by muse, mutect2, varscan2
- BLVRA | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV55515769; called by muse, mutect2, varscan2
- BMPR2 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV101001613, COSV65812397; called by muse, mutect2, varscan2
- BORCS5 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.057); catalogued as COSV53804222; called by muse, mutect2, varscan2
- BRWD1 | c.2313A>G p.I771M | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1204990243, COSV60894925; called by muse, mutect2, varscan2
- BTBD9 | c.887T>G p.L296* | Nonsense Mutation (SNP) | VAF 62/202 reads (31%) | catalogued as COSV100022409, COSV58424044; called by muse, mutect2, varscan2
- BTN1A1 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 66/268 reads (25%) | catalogued as COSV99764462; called by muse, mutect2, varscan2
- C10orf90 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV52960893, COSV52964183; called by muse, mutect2, varscan2
- C4orf45 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV101465151, COSV71701372; called by muse, mutect2, varscan2
- C7orf31 | c.1329G>C p.W443C | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV52219355; called by muse, mutect2, varscan2
- C8G | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.665); catalogued as rs753450750, COSV56403041; called by muse, mutect2, varscan2
- CACNA1B | c.6799G>A p.E2267K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.428); catalogued as rs900919958, COSV53141190; called by muse, mutect2, varscan2
- CALCB | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV60834576; called by muse, mutect2, varscan2
- CAMSAP1 | c.2931G>T p.E977D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.197); catalogued as COSV56726432; called by muse, mutect2, varscan2
- CARD18 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.036); catalogued as COSV73233182, COSV73233218; called by muse, mutect2, varscan2
- CATSPER1 | c.2065-1G>A p.X689_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as COSV56412690; called by muse, mutect2
- CCDC183 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs567970505, COSV100273626; called by muse, mutect2, varscan2
- CCN1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as rs768362037, COSV71704266; called by muse, mutect2, varscan2
- CCT5 | c.499C>G p.Q167E | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs199552031, COSV54725032; called by muse, mutect2, varscan2
- CDC73 | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated (0.85); PolyPhen benign (0.05); catalogued as COSV66469530; called by muse, mutect2, varscan2
- CDH17 | c.621T>A p.Y207* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | catalogued as COSV99217800; called by muse, mutect2, varscan2
- CDH18 | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56948086; called by muse, mutect2, varscan2
- CDH5 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV58519199; called by muse, mutect2, varscan2
- CDK12 | c.767C>A p.S256* | Nonsense Mutation (SNP) | VAF 57/149 reads (38%) | catalogued as COSV101420402, COSV101420508; called by muse, mutect2, varscan2
- CDK9 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as rs371317161; called by muse, mutect2, varscan2
- CDKN2AIP | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs1484456993, COSV56627803; called by muse, mutect2, varscan2
- CEP104 | c.2746A>T p.K916* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100986692; called by muse, mutect2, varscan2
- CEP126 | c.2477C>G p.P826R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV54829054; called by muse, mutect2, varscan2
- CEP131 | c.2455G>A p.E819K (on ENST00000269392 / NM_001319228.2; = p.E816K on NM_014984.4) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV53955285; called by muse, mutect2, varscan2
- CEP162 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV57622701; called by muse, mutect2, varscan2
- CERKL | c.1073C>T p.A358V (on ENST00000339098 / NM_001030311.2; = p.A332V on NM_201548.5) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs868737394, COSV59211641; called by muse, mutect2, varscan2
- CERT1 | c.1663A>G p.M555V (on ENST00000405807 / NM_001130105.1; = p.M427V on NM_005713.3) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV54662918; called by muse, mutect2, varscan2
- CFAP20DC | c.907G>A p.E303K (on ENST00000482387 / NM_001351530.2; = p.E178K on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.506); catalogued as COSV55925222; called by muse, mutect2, varscan2
- CFAP52 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100235468; called by muse, mutect2, varscan2
- CFAP94 | c.1670C>T p.T557I (on ENST00000320267 / NM_001352064.2; = p.T563I on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs911414197, COSV57235345; called by muse, mutect2, varscan2
- CFHR1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs1410660558, COSV100258927; called by muse, mutect2, varscan2
- CHD3 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV57878645; called by muse, mutect2, varscan2
- CHTF8 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs767899950, COSV54708539; called by muse, mutect2, varscan2
- CIAPIN1 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs533025302, COSV67953544; called by muse, varscan2
- CILP | c.1029-1G>A p.X343_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV56027090; called by muse, mutect2
- CIZ1 | c.1101G>C p.Q367H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); catalogued as COSV52973624; called by muse, mutect2, varscan2
- CLDN16 | c.87G>C p.W29C | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795763, COSV53228913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLIC5 | c.1177G>A p.D393N (on ENST00000185206 / NM_001370649.1; = p.D234N on NM_016929.5) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV51763176; called by muse, mutect2, varscan2
- CLPTM1L | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.438); catalogued as COSV57991993; called by muse, mutect2, varscan2
- CLTC | c.2236A>G p.R746G | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52251270; called by muse, mutect2, varscan2
- CMTM1 | c.127A>T p.N43Y (on ENST00000457188 / NM_181269.3; = p.N160Y on NM_052999.4) | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV50451620; called by muse, mutect2, varscan2
- CMYA5 | c.8569G>A p.D2857N | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV71408455; called by muse, mutect2, varscan2
- CNGB3 | c.1910T>C p.I637T | Missense Mutation (SNP) | VAF 68/301 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV60695333; called by muse, mutect2, varscan2
- CNTROB | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as rs149102058; called by muse, mutect2, varscan2
- COASY | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs1310804717, COSV55898884; called by muse, mutect2, varscan2
- COG7 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV56152173; called by muse, mutect2, varscan2
- COL16A1 | c.2297T>C p.L766P | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs778153690, COSV54711469; called by muse, mutect2, varscan2
- COPS7B | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV62601520; called by muse, mutect2, varscan2
- CORO1C | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as COSV54598178; called by muse, mutect2, varscan2
- CORO7 | c.1765G>T p.V589L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV52032819; called by muse, mutect2, varscan2
- CP | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52832816; called by muse, mutect2, varscan2
- CPED1 | c.1900C>G p.P634A | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as rs756904152, COSV60009270; called by muse, mutect2, varscan2
- CPLANE1 | c.8155G>A p.E2719K | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs1466899045, COSV57069588; called by muse, mutect2, varscan2
- CRAT | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as rs763023389, COSV58876641; called by muse, mutect2, varscan2
- CREB3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); catalogued as COSV59210430; called by muse, mutect2, varscan2
- CSMD1 | c.2306T>A p.V769D (on ENST00000520002; = p.V768D on NM_033225.6) | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59323096, COSV59361951; called by muse, mutect2, varscan2
- CSPP1 | c.2149G>A p.E717K (on ENST00000676605; = p.E676K on NM_024790.6) | Missense Mutation (SNP) | VAF 198/326 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV51590034; called by muse, mutect2, varscan2
- CSRP1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.155); catalogued as rs1218036571, COSV60637713; called by muse, mutect2, varscan2
- CST1 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749007247, COSV59055994, COSV59056019; called by muse, mutect2, varscan2
- CUZD1 | c.1802del p.Y601Sfs*9 | Frame Shift Del (DEL) | VAF 66/224 reads (29%) | catalogued as COSV59027362, COSV59027590; called by mutect2, pindel, varscan2
- CYB561D1 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1228787582, COSV60203935, COSV60205691; called by muse, mutect2, varscan2
- CYP2F1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV58528504; called by muse, mutect2, varscan2
- DCAF1 | c.663G>C p.M221I | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60045643; called by muse, mutect2, varscan2
- DCAF15 | c.392A>G p.D131G | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV54337310; called by muse, mutect2, varscan2
- DCAF6 | c.2563G>A p.E855K (on ENST00000312263 / NM_001349778.1; = p.E875K on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as rs1226610172, COSV56581812, COSV56582859; called by muse, mutect2, varscan2
- DCHS1 | c.4678C>A p.P1560T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1430318803, COSV55040447; called by muse, mutect2, varscan2
- DCHS1 | c.3491C>T p.T1164I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.815); catalogued as COSV55040454; called by muse, mutect2, varscan2
- DCLRE1A | c.2155T>G p.Y719D | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV63749442; called by muse, mutect2, varscan2
- DCUN1D5 | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.401); catalogued as rs138589410; called by muse, mutect2, varscan2
- DDB1 | c.2989C>T p.L997F | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.349); catalogued as COSV57104894; called by muse, mutect2, varscan2
- DDX11 | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV99300057; called by muse, mutect2, varscan2
- DDX50 | c.2044T>C p.W682R | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1482421534, COSV65293085; called by muse, mutect2, varscan2
- DDX59 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58753383; called by muse, mutect2, varscan2
- DGKE | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV52350902; called by muse, mutect2, varscan2
- DGKG | c.62C>G p.S21* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99404061; called by muse, mutect2, varscan2
- DHX15 | c.1845G>A p.M615I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV61028598; called by muse, mutect2, varscan2
- DHX16 | c.3052G>A p.A1018T | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs1488615230, COSV53315645; called by muse, mutect2, varscan2
- DHX16 | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | catalogued as COSV100906132; called by muse, mutect2, varscan2
- DHX58 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52427518; called by muse, mutect2, varscan2
- DIPK1C | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.227); catalogued as rs748356608, COSV59726117; called by muse, mutect2, varscan2
- DLC1 | c.4264C>T p.H1422Y (on ENST00000276297 / NM_001348081.2; = p.H985Y on NM_006094.5) | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52319819; called by muse, mutect2, varscan2
- DLX2 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as COSV52232631; called by muse, mutect2, varscan2
- DNAH8 | c.822G>C p.R274S | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV59470168; called by muse, mutect2, varscan2
- DNAH9 | c.11548C>T p.R3850C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs765859979, COSV52346391; called by muse, mutect2, varscan2
- DNAI4 | c.871A>T p.M291L | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV64019551; called by muse, mutect2, varscan2
- DNAJB13 | c.597A>C p.E199D | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60270362; called by muse, mutect2, varscan2
- DNAJC13 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV53455550; called by muse, mutect2, varscan2
- DNAJC13 | c.6703G>A p.E2235K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV53455559; called by muse, mutect2, varscan2
- DNAJC17 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as COSV55026051; called by muse, mutect2, varscan2
- DNAJC21 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs1414892776, COSV57761909; called by muse, mutect2, varscan2
- DPEP2 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1244024705, COSV52055264, COSV52055396; called by muse, mutect2, varscan2
- DPM3 | c.26G>A p.W9* (on ENST00000341298; = p.W39* on NM_018973.3) | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100310456; called by muse, mutect2, varscan2
- DSC1 | c.1020T>G p.I340M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV57149556; called by muse, mutect2, varscan2
- DSP | c.8354A>G p.Y2785C | Missense Mutation (SNP) | VAF 85/125 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781408330, COSV60940405; called by muse, mutect2, varscan2
- DUSP8 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.147); catalogued as COSV59031015; called by muse, varscan2
- DXO | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 51/115 reads (44%) | catalogued as COSV100514804; called by muse, mutect2, varscan2
- E2F8 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs924165322, COSV51465361; called by muse, mutect2, varscan2
- E2F8 | c.54G>C p.M18I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100001484, COSV51465380; called by muse, mutect2, varscan2
- EEF2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58580433; called by muse, mutect2, varscan2
- EFHB | c.932G>C p.R311T | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs200170380, COSV55551817; called by muse, mutect2, varscan2
- EGF | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV54482713; called by muse, mutect2, varscan2
- EGR4 | c.1237C>T p.Q413* (on ENST00000545030; = p.Q310* on NM_001965.4) | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV101474262; called by muse, mutect2, varscan2
- EHD1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57736073; called by muse, mutect2, varscan2
- EID1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.776); catalogued as rs1236981975, COSV60114749; called by muse, mutect2, varscan2
- ELOVL1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.542); catalogued as COSV60522718; called by muse, mutect2, varscan2
- ENPP5 | c.653T>G p.L218R | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780649920, COSV57909597; called by muse, mutect2, varscan2
- ERGIC1 | c.588T>G p.Y196* | Nonsense Mutation (SNP) | VAF 35/68 reads (51%) | catalogued as COSV101195011; called by muse, mutect2, varscan2
- ERLIN2 | c.216G>C p.K72N | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52419901, COSV52421542; called by muse, mutect2, varscan2
- EXOC3 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100155487; called by muse, mutect2, varscan2
- EXT1 | c.491A>C p.D164A | Missense Mutation (SNP) | VAF 170/265 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as CD065714, COSV65483230; called by muse, mutect2, varscan2
- F9 | c.1171T>A p.Y391N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.144); catalogued as COSV54381896; called by muse, mutect2, varscan2
- FAF2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs766728205, COSV56132525; called by muse, mutect2, varscan2
- FAM118B | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64157509; called by muse, mutect2, varscan2
- FAM124A | c.488G>A p.R163Q (on ENST00000322475 / NM_001242312.2; = p.R199Q on NM_145019.4) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1488909381, COSV54479062; called by muse, mutect2, varscan2
- FAM160B1 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65086792; called by muse, mutect2, varscan2
- FAM161B | c.814G>A p.E272K (on ENST00000651776; = p.E209K on NM_152445.3) | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54103627; called by muse, mutect2, varscan2
- FAM163A | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.284); catalogued as COSV59205135; called by muse, mutect2, varscan2
- FAM83H | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT tolerated (0.69); PolyPhen benign (0.079); catalogued as rs1554624080, COSV66354372; called by muse, mutect2, varscan2
- FAT2 | c.1520T>G p.I507S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV55826434; called by muse, mutect2, varscan2
- FBLN1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV53052151; called by muse, mutect2, varscan2
- FBXO43 | c.1826T>C p.L609P | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV71053495; called by muse, mutect2, varscan2
- FCGBP | c.3239G>A p.S1080N | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1219935685; called by muse, mutect2, varscan2
- FIGN | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV60770135; called by muse, mutect2, varscan2
- FILIP1 | c.3585A>G p.I1195M | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs776414914, COSV52737359; called by muse, mutect2, varscan2
- FNBP1 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.671); catalogued as COSV63089463; called by muse, mutect2, varscan2
- FNDC3A | c.266A>G p.N89S (on ENST00000492622 / NM_001079673.2; = p.N33S on NM_014923.5) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.571); catalogued as rs774395306, COSV65696263; called by muse, mutect2, varscan2
- FOXF1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52288020, COSV99296548; called by muse, mutect2, varscan2
- FRAS1 | c.3196C>A p.H1066N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99354749; called by muse, mutect2
- FRYL | c.5212A>T p.N1738Y | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV51956770; called by muse, mutect2, varscan2
- FRZB | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs1382959784, COSV54555483, COSV99717500; called by muse, mutect2, varscan2
- FSCN1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61018439; called by muse, mutect2, varscan2
- FTH1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV56445258; called by muse, mutect2, varscan2
- FTO | c.980C>G p.S327* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | catalogued as COSV101150753; called by muse, mutect2, varscan2
- FYCO1 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56118514; called by mutect2, varscan2
- GAB2 | c.229A>C p.K77Q (on ENST00000361507 / NM_080491.3; = p.K39Q on NM_012296.3) | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV60870088; called by muse, mutect2, varscan2
- GALNT2 | c.1186T>G p.Y396D | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64196715; called by muse, mutect2, varscan2
- GBP1 | c.1441A>G p.T481A | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100976289; called by muse, mutect2, varscan2
- GFRA1 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs781107507, COSV62608101, COSV62609176; called by muse, mutect2, varscan2
- GGCX | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 102/186 reads (55%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV52089769; called by muse, mutect2, varscan2
- GJB5 | c.794G>C p.R265P | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.187); catalogued as COSV58356482, COSV58356837; called by muse, mutect2, varscan2
- GLB1L3 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1434632591, COSV66282783; called by muse, mutect2, varscan2
- GLTPD2 | c.127C>G p.P43A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100165334; called by muse, mutect2, varscan2
- GMCL1 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs1412137445, COSV57002912; called by muse, mutect2, varscan2
- GNA11 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs374089777; called by muse, varscan2
- GNL2 | c.1414C>G p.Q472E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV66081403; called by muse, mutect2, varscan2
- GOPC | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.366); catalogued as rs1255848371, COSV50003371; called by muse, mutect2, varscan2
- GPA33 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs770755130, COSV63301841; called by muse, mutect2, varscan2
- GPC4 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV63698475; called by muse, mutect2, varscan2
- GPCPD1 | c.1619C>A p.S540Y | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1478371341, COSV66831496; called by muse, mutect2, varscan2
- GPR107 | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV61281656; called by muse, mutect2, varscan2
- GPR137B | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV63991401, COSV99053742; called by muse, mutect2, varscan2
- GPR160 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV63473349; called by muse, mutect2, varscan2
- GRIA4 | c.2233G>C p.V745L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56912252; called by muse, mutect2, varscan2
- GRIP1 | c.1483G>A p.E495K (on ENST00000359742 / NM_001379345.1; = p.E443K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54035929; called by muse, mutect2, varscan2
- GSG1 | c.636T>A p.G212= (on ENST00000651961 / NM_001080555.4; = p.S218T on NM_031289.5) | Splice Region (SNP) | VAF 58/123 reads (47%) | catalogued as COSV52196524; called by muse, mutect2, varscan2
- GYS2 | c.1489G>C p.V497L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53927010; called by muse, mutect2, varscan2
- H1-1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 52/77 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs763346591, COSV55120249; called by muse, mutect2, varscan2
- H1-7 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58602523, COSV58602816; called by muse, mutect2, varscan2
- HDAC11 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs775294586, COSV55474200; called by muse, mutect2, varscan2
- HDAC9 | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 56/68 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV101286986, COSV67781531; called by muse, mutect2, varscan2
- HEATR5B | c.4482G>C p.L1494F | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV51856816; called by muse, mutect2, varscan2
- HECTD4 | c.5097C>T p.T1699= | Splice Region (SNP) | VAF 22/54 reads (41%) | catalogued as rs886239473, COSV66397078; called by muse, mutect2, varscan2
- HEPN1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.005); catalogued as COSV53430026; called by muse, mutect2, varscan2
- HGSNAT | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.443); catalogued as rs550696803, CD065734, COSV99925422; called by muse, varscan2
- HNRNPH1 | c.375A>C p.E125D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.189); catalogued as COSV61487712; called by muse, mutect2, varscan2
- HNRNPR | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1183839557, COSV56423380; called by muse, mutect2, varscan2
- HOXA11 | c.798T>G p.I266M | Missense Mutation (SNP) | VAF 97/116 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50054147; called by muse, mutect2, varscan2
- HOXB8 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs757836046, COSV53311242; called by muse, mutect2, varscan2
- HSD17B2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52277810; called by muse, mutect2, varscan2
- HSPA2 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.672); catalogued as COSV55970861; called by muse, mutect2, varscan2
- HSPB8 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as rs757293016, COSV56136872, COSV56137127, COSV56137340; called by muse, mutect2, varscan2
- HSPG2 | c.2683A>G p.K895E | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65975304; called by muse, mutect2, varscan2
- ICE1 | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as rs201436327, COSV56829757; called by muse, mutect2, varscan2
- ID1 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs746413130, COSV65888790; called by muse, mutect2, varscan2
- IGF2BP3 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.66); catalogued as COSV51690548; called by muse, mutect2, varscan2
- IGSF9B | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV58071121; called by muse, mutect2, varscan2
- IHO1 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56509349; called by muse, mutect2, varscan2
- IKZF3 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53105319, COSV53106143; called by muse, mutect2, varscan2
- IL11RA | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52405430; called by muse, mutect2, varscan2
- IL33 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs778800068, COSV67342781; called by muse, mutect2, varscan2
- INO80 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62741129; called by muse, mutect2, varscan2
- INO80B | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as rs1000432692, COSV51971042; called by muse, mutect2, varscan2
- INTS1 | c.5059C>A p.Q1687K | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs1228253602, COSV67178997; called by muse, mutect2, varscan2
- INVS | c.3028G>C p.E1010Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.354); catalogued as rs375774619, COSV52447181, COSV52449984; called by muse, mutect2, varscan2
- IPO9 | c.2782G>A p.V928I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs767767384, COSV64235055; called by muse, mutect2, varscan2
- IQGAP2 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1320253941, COSV57178854; called by muse, mutect2, varscan2
- IREB2 | c.2214A>C p.E738D | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV51925356; called by muse, mutect2, varscan2
- IRF7 | c.808G>A p.E270K (on ENST00000397566; = p.E257K on NM_001572.5) | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.72); PolyPhen benign (0.182); catalogued as rs1160609325, COSV52750603, COSV52757118, COSV99199614; called by muse, mutect2, varscan2
- ITCH | c.317T>G p.L106* | Nonsense Mutation (SNP) | VAF 38/50 reads (76%) | catalogued as COSV99392983; called by muse, mutect2, varscan2
- ITGA5 | c.1747G>C p.D583H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.421); catalogued as COSV53219845; called by muse, mutect2, varscan2
- JMJD1C | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV67865961; called by muse, mutect2, varscan2
- KANSL1 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV52267144, COSV52272385; called by muse, mutect2, varscan2
- KAT2A | c.1905G>T p.K635N | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV52427523; called by muse, mutect2, varscan2
- KCNIP4 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV54844241, COSV54844598; called by muse, mutect2, varscan2
- KCNN1 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV55840962; called by muse, mutect2, varscan2
- KCNS2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV54640111; called by muse, mutect2, varscan2
- KDM3A | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs760305076, COSV57224424; called by muse, mutect2, varscan2
- KDM3A | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV57218679, COSV57224528; called by muse, mutect2, varscan2
- KDM6A | c.3308T>C p.L1103P | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV65043768; called by muse, mutect2, varscan2
- KIAA1217 | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs137864034, COSV100286792; called by muse, mutect2, varscan2
- KIF15 | c.4030G>C p.V1344L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV58163723; called by muse, mutect2, varscan2
- KIF17 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV56121227; called by muse, mutect2
- KIF24 | c.1460G>C p.R487P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61456813; called by muse, mutect2, varscan2
- KIF2B | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV52129607, COSV52133967; called by muse, mutect2, varscan2
- KLC2 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs1302275544, COSV57583763; called by muse, mutect2, varscan2
- KLHDC7B | c.1018G>A p.E340K (on ENST00000395676; = p.E981K on NM_138433.5) | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as rs773502147, COSV67464512, COSV67465067; called by muse, mutect2, varscan2
- KLHL11 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV59861539, COSV59861587; called by muse, mutect2, varscan2
- KNTC1 | c.1547T>G p.L516R | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV61082829; called by muse, mutect2, varscan2
- KRT33B | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs759663859, COSV52441972; called by muse, mutect2, varscan2
- KRT77 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV59240944; called by muse, mutect2, varscan2
- KRT77 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.106); catalogued as COSV59240956; called by muse, mutect2, varscan2
- KRTAP19-5 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as COSV61859365; called by muse, mutect2, varscan2
- LARP1B | c.2536T>C p.F846L | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1431142599, COSV52801285; called by muse, mutect2, varscan2
- LAYN | c.587G>A p.R196K (on ENST00000375615 / NM_001258390.1; = p.R188K on NM_178834.5) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs1280737650, COSV65105268; called by muse, mutect2, varscan2
- LFNG | c.486C>G p.N162K (on ENST00000222725 / NM_001040167.2; = p.N33K on NM_002304.2) | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV56070307; called by muse, mutect2, varscan2
- LGSN | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.045); catalogued as COSV65728078; called by muse, mutect2, varscan2
- LIG3 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as COSV52009846; called by muse, mutect2, varscan2
- LIMD1 | c.241_250del p.G81Wfs*14 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | catalogued as COSV56269264; called by mutect2, varscan2
- LIMK2 | c.1174A>T p.I392F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1402237296, COSV59183799; called by muse, mutect2, varscan2
- LONRF2 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV66541800; called by muse, mutect2, varscan2
- LPIN2 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV55242751; called by muse, mutect2, varscan2
- LRP2 | c.1923_1943del p.S642_V648del | In Frame Del (DEL) | VAF 15/42 reads (36%) | catalogued as COSV55567097; called by mutect2, pindel, varscan2
- LRRC32 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.069); catalogued as COSV52632062, COSV52634683; called by muse, mutect2, varscan2
- LRRC36 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.319); catalogued as rs1393870225, COSV52081439; called by muse, mutect2, varscan2
- LRRN3 | c.866T>C p.L289S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57817324, COSV57822667; called by muse, mutect2, varscan2
- LSM2 | c.58A>C p.K20Q | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65151036; called by muse, mutect2, varscan2
- LTBP3 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57242957; called by muse, mutect2, varscan2
- MACF1 | c.7741G>C p.E2581Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV57136129; called by muse, mutect2, varscan2
- MACO1 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs1192725301, COSV65477652; called by muse, mutect2, varscan2
- MAD2L1BP | c.271T>G p.Y91D | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474697881, COSV64679246, COSV64679435; called by muse, mutect2, varscan2
- MAML1 | c.395A>T p.D132V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52987945; called by muse, mutect2, varscan2
- MAP3K21 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV64042325; called by muse, mutect2, varscan2
- MAP7D1 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); catalogued as COSV60217851; called by muse, mutect2, varscan2
- MAST1 | c.2926A>T p.K976* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99263470; called by muse, mutect2, varscan2
- MATN4 | c.1793A>G p.E598G (on ENST00000372754; = p.E557G on NM_003833.4) | Missense Mutation (SNP) | VAF 75/87 reads (86%) | PolyPhen benign (0.019); catalogued as rs1296310740, COSV61352349; called by muse, mutect2, varscan2
- MEA1 | c.191_209del p.G64Afs*4 | Frame Shift Del (DEL) | VAF 34/149 reads (23%) | catalogued as COSV55146042; called by mutect2, pindel, varscan2
- MED13 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.275); catalogued as COSV67265964; called by muse, mutect2, varscan2
- MED26 | c.1199G>C p.R400P | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV54662075, COSV54662253; called by muse, mutect2, varscan2
- MEIS1 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99715630; called by muse, mutect2, varscan2
- METTL23 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 108/216 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV57974569; called by muse, mutect2, varscan2
- METTL3 | c.1536T>G p.H512Q | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV52970572; called by muse, mutect2, varscan2
- METTL3 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52970576; called by muse, mutect2
- MFAP1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV51038398, COSV51040424; called by muse, mutect2, varscan2
- MFSD11 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100334179; called by muse, mutect2, varscan2
- MGAT4A | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as COSV53849595; called by muse, mutect2, varscan2
- MIER1 | c.1352T>G p.L451R (on ENST00000355356 / NM_001077701.3; = p.L468R on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as COSV62531507; called by muse, mutect2, varscan2
- MINDY4 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs757043983, COSV54672348; called by muse, mutect2, varscan2
- MIOS | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 116/152 reads (76%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV60770010; called by muse, mutect2, varscan2
- MOAP1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT tolerated (0.83); PolyPhen benign (0.152); catalogued as COSV52092867; called by muse, mutect2, varscan2
- MREG | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54374869, COSV54375171; called by muse, mutect2, varscan2
- MRPL32 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV56239848; called by muse, mutect2, varscan2
- MSL3 | c.785G>A p.R262K (on ENST00000312196 / NM_078629.4; = p.R96K on NM_006800.4) | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56495127; called by muse, mutect2, varscan2
- MTFR1L | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 46/114 reads (40%) | catalogued as COSV100962557; called by muse, mutect2, varscan2
- MTIF2 | c.1552G>T p.V518L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV55053294; called by muse, mutect2, varscan2
- MTMR6 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.084); catalogued as COSV67809292; called by muse, mutect2, varscan2
- MUC16 | c.29633G>T p.G9878V | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.479); catalogued as COSV101201073, COSV67482761; called by muse, mutect2, varscan2
- MUC16 | c.4647A>C p.E1549D | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67482764; called by muse, mutect2, varscan2
- MYF6 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as rs1157752196, COSV57352769; called by muse, mutect2, varscan2
- MYH10 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52607561; called by muse, mutect2, varscan2
- MYO1B | c.3288G>A p.E1096= (on ENST00000304164; = p.E1038= on NM_012223.5) | Splice Region (SNP) | VAF 36/85 reads (42%) | catalogued as rs772361283, COSV58435980; called by muse, mutect2, varscan2
- MYO1F | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57795574, COSV57798681; called by muse, mutect2, varscan2
- MYO9A | c.6146C>T p.S2049F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61855277; called by muse, mutect2, varscan2
- MYOM2 | c.3151A>T p.I1051F | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (1); PolyPhen probably damaging (0.915); catalogued as COSV50730954, COSV50750300; called by muse, mutect2, varscan2
- MYRF | c.1642G>A p.A548T (on ENST00000278836 / NM_001127392.3; = p.A539T on NM_013279.4) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV53892269, COSV99606899; called by muse, mutect2, varscan2
- NABP1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV57138372; called by muse, mutect2, varscan2
- NAGLU | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as COSV56795758; called by muse, mutect2
- NAV2 | c.946G>A p.D316N (on ENST00000396087 / NM_001244963.2; = p.D293N on NM_145117.5) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV62330265; called by muse, mutect2, varscan2
- NBEA | c.6829C>T p.R2277* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | catalogued as COSV59826495; called by muse, mutect2, varscan2
- NBPF1 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 68/1180 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV99844774; called by muse, mutect2
- NCAPG | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52272021; called by muse, mutect2, varscan2
- NDUFAF3 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV58246337, COSV58246741; called by muse, mutect2, varscan2
- NDUFB5 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.663); catalogued as rs373322203, COSV52019581, COSV52020878; called by muse, mutect2, varscan2
- NEDD4L | c.1885G>A p.E629K (on ENST00000400345 / NM_001144967.3; = p.E609K on NM_015277.6) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56850293, COSV99893625; called by muse, mutect2, varscan2
- NEK1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101455602, COSV71457580; called by muse, mutect2, varscan2
- NF1 | c.2221T>C p.F741L | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62214231; called by muse, mutect2, varscan2
- NLRX1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV52707726; called by muse, mutect2, varscan2
- NOL3 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs1304978152, COSV50458774; called by muse, mutect2, varscan2
- NOX3 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as COSV50156224; called by muse, mutect2, varscan2
- NPAT | c.3437C>T p.S1146L | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.369); catalogued as COSV53720363; called by muse, mutect2, varscan2
- NR4A2 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1452459489, COSV59895013; called by muse, mutect2, varscan2
- NRK | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 8/10 reads (80%) | catalogued as COSV99687522, COSV99688747; called by muse, varscan2
- NUDCD1 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.18); catalogued as COSV53459354; called by muse, mutect2, varscan2
- NUMB | c.489_509del p.A164_Q170del (on ENST00000355058; = p.A153_Q159del on NM_003744.5) | In Frame Del (DEL) | VAF 23/29 reads (79%) | catalogued as COSV61831450; called by mutect2, pindel
- NUP85 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749309995, COSV55458266; called by muse, mutect2, varscan2
- OASL | c.1348A>G p.I450V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as rs374637093; called by muse, mutect2, varscan2
- OASL | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57479891, COSV57479921; called by muse, mutect2, varscan2
- OLFML3 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV57436533; called by muse, mutect2, varscan2
- OOEP | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV64858970, COSV64859075; called by muse, mutect2, varscan2
- OR51E2 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV67808354; called by muse, mutect2, varscan2
- OR52N4 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV57891851; called by muse, mutect2, varscan2
- OR5B21 | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.254); catalogued as COSV64482159; called by muse, mutect2, varscan2
- OR5L2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV65724532, COSV65724588; called by muse, mutect2, varscan2
- OR5M11 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs745349090, COSV73141967; called by muse, mutect2, varscan2
- OSBPL3 | c.1318A>G p.S440G | Missense Mutation (SNP) | VAF 158/193 reads (82%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV57660620; called by muse, mutect2, varscan2
- OSGIN2 | c.1106C>A p.S369* | Nonsense Mutation (SNP) | VAF 43/245 reads (18%) | catalogued as COSV99858544; called by muse, mutect2, varscan2
- OTX1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV56995651; called by muse, mutect2, varscan2
- PAIP2B | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV99731747; called by muse, mutect2
- PAQR7 | c.761T>C p.F254S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1169323474, COSV65352058; called by muse, mutect2, varscan2
- PAQR7 | c.760T>G p.F254V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1400449917, COSV65352062; called by muse, mutect2, varscan2
- PARP1 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 194/319 reads (61%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV64691652; called by muse, mutect2, varscan2
- PBOV1 | c.271_279del p.K91_S93del | In Frame Del (DEL) | VAF 30/45 reads (67%) | catalogued as COSV52466473; called by mutect2, pindel, varscan2
- PBX2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as rs773626213, COSV66708712; called by muse, mutect2, varscan2
- PCDH1 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.81); catalogued as COSV54617896; called by muse, mutect2, varscan2
- PCDH15 | c.3463G>A p.E1155K | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV57366158; called by muse, mutect2, varscan2
- PCDH7 | c.1281C>A p.D427E | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.399); catalogued as COSV62341980; called by muse, mutect2, varscan2
- PCDHGB1 | c.1343T>G p.F448C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54003327; called by muse, mutect2, varscan2
- PCDHGB6 | c.749G>C p.S250T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.219); catalogued as COSV54003345; called by muse, mutect2, varscan2
- PCM1 | c.3760G>A p.D1254N | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59588183; called by muse, mutect2, varscan2
- PCNT | c.8947C>T p.L2983F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs372356069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDS5B | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV59731842; called by muse, mutect2, varscan2
- PDS5B | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV59731853; called by muse, mutect2, varscan2
- PEX1 | c.2464C>T p.L822F | Missense Mutation (SNP) | VAF 81/101 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV50409601; called by muse, mutect2, varscan2
- PEX26 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61605058; called by muse, mutect2
- PFAS | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58982335; called by muse, mutect2, varscan2
- PGRMC2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs929612598, COSV56481086; called by muse, mutect2, varscan2
- PHACTR3 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63032231; called by muse, mutect2, varscan2
- PIBF1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as COSV58326793; called by muse, mutect2, varscan2
- PIK3CD | c.3020C>T p.T1007I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV63130766; called by muse, varscan2
- PIKFYVE | c.3677C>T p.S1226F | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52237682, COSV52246676; called by muse, mutect2, varscan2
- PITPNM2 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54905956; called by muse, mutect2, varscan2
- PIWIL1 | c.2251C>T p.Q751* | Nonsense Mutation (SNP) | VAF 40/107 reads (37%) | catalogued as COSV99806754; called by muse, mutect2, varscan2
- PKD2 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs748914485, COSV52940320, COSV52941413; called by muse, mutect2, varscan2
- PKHD1L1 | c.9874T>G p.F3292V | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV65737270, COSV65749502; called by muse, mutect2, varscan2
- PKP2 | c.2308A>T p.T770S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs1249551566, COSV50741408; called by muse, mutect2, varscan2
- PLEKHA5 | c.1819A>G p.S607G | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54708905; called by muse, mutect2, varscan2
- PLIN2 | c.31-1G>A p.X11_splice | Splice Site (SNP) | VAF 34/67 reads (51%) | catalogued as COSV52804083; called by muse, mutect2, varscan2
- PLSCR1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV61013440; called by muse, mutect2, varscan2
- PLXNC1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1405758789, COSV51581401; called by muse, mutect2, varscan2
- POLDIP2 | c.159C>T p.S53= | Splice Region (SNP) | VAF 13/27 reads (48%) | catalogued as rs1555581118, COSV99134847; called by muse, mutect2, varscan2
- POLR3F | c.644A>C p.E215A | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV66473226; called by muse, mutect2, varscan2
- PPFIBP2 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as rs1470891109, COSV100206805; called by muse, mutect2, varscan2
- PPHLN1 | c.381T>G p.N127K | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV56734845; called by muse, mutect2, varscan2
- PPIG | c.1030C>G p.P344A | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53645067; called by muse, mutect2, varscan2
- PPIL2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 112/138 reads (81%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as rs770568621, COSV58606368; called by muse, mutect2, varscan2
- PPP1R26 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV63356767; called by muse, mutect2, varscan2
- PPP3CA | c.1475C>G p.S492C | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.353); catalogued as rs771722172, COSV59928859; called by muse, mutect2, varscan2
- PRKACG | c.275A>G p.E92G | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55254630; called by muse, mutect2
- PRKACG | c.273C>G p.N91K | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs758425612, COSV55252193, COSV55254638; called by muse, mutect2
- PRKG1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.899); catalogued as rs372471361; called by muse, varscan2
- PRPF6 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV53875937; called by muse, mutect2, varscan2
- PRR7 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.264); catalogued as rs768516188, COSV52791758; called by muse, varscan2
- PRRT3 | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55978213; called by muse, mutect2, varscan2
- PRUNE1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV54959337; called by muse, mutect2, varscan2
- PSMC5 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV56741216; called by muse, mutect2, varscan2
- PSMD1 | c.1494A>T p.K498N | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV58082028; called by muse, mutect2, varscan2
- PTGER4 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100201698; called by muse, mutect2
- PTPRE | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV54556311, COSV54559902; called by muse, mutect2, varscan2
- PTPRN | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779829092, COSV55350894; called by muse, mutect2, varscan2
- PXK | c.1362G>C p.E454D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs754275774, COSV57091876; called by muse, mutect2, varscan2
- PXN | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV57218561; called by muse, mutect2
- QTRT2 | c.1055C>A p.S352Y | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV55559764, COSV55561181; called by muse, mutect2, varscan2
- RAB38 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760114172, COSV54712089; called by muse, mutect2, varscan2
- RACK1 | c.531G>A p.W177* | Nonsense Mutation (SNP) | VAF 33/67 reads (49%) | catalogued as COSV100163433; called by muse, mutect2, varscan2
- RAD54L | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV64336749; called by muse, mutect2, varscan2
- RALGPS2 | c.1486T>C p.Y496H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs775320151, COSV62679205; called by muse, mutect2, varscan2
- RAP1GAP | c.613-1G>A p.X205_splice | Splice Site (SNP) | VAF 31/81 reads (38%) | catalogued as COSV51576110; called by muse, mutect2, varscan2
- RAPGEF6 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754143428, COSV57252798; called by muse, mutect2, varscan2
- RAPH1 | c.1-1G>A p.X1_splice | Splice Site (SNP) | VAF 26/92 reads (28%) | catalogued as COSV57356059; called by muse, mutect2, varscan2
- RASGRF1 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as COSV101369731; called by muse, mutect2, varscan2
- RASL11B | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 60/155 reads (39%) | catalogued as COSV99954511; called by muse, mutect2, varscan2
- RBBP8 | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59092827; called by muse, mutect2, varscan2
- RBMS2 | c.1065T>C p.Y355= | Splice Region (SNP) | VAF 33/80 reads (41%) | catalogued as COSV56265308; called by muse, mutect2, varscan2
- RC3H1 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV51209235; called by muse, mutect2, varscan2
- RCOR3 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 103/198 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770512731, COSV65366530; called by muse, mutect2, varscan2
- REV1 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV51487547, COSV51491561; called by muse, mutect2, varscan2
- RGS17 | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52810190; called by muse, mutect2, varscan2
- RICTOR | c.459G>A p.M153I | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV57127865; called by muse, mutect2, varscan2
- RIPPLY2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs763323503, COSV63762351; called by muse, mutect2, varscan2
- RIT2 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.839); catalogued as COSV58672748; called by muse, mutect2, varscan2
- RLN3 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as rs1192489666, COSV54602305; called by muse, mutect2, varscan2
- RNF123 | c.3866T>G p.F1289C | Missense Mutation (SNP) | VAF 92/169 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1001399602, COSV57539631; called by muse, mutect2, varscan2
- RNF19A | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 119/172 reads (69%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.798); catalogued as rs751593516, COSV61994358; called by muse, mutect2, varscan2
- RNF2 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV62280181; called by muse, mutect2, varscan2
- RNF34 | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV63443123, COSV63443153; called by muse, mutect2, varscan2
- ROBO1 | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71397250; called by muse, mutect2, varscan2
- RPTOR | c.2022T>A p.Y674* | Nonsense Mutation (SNP) | VAF 91/206 reads (44%) | catalogued as COSV100156903; called by muse, mutect2
- RTN4 | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV58271960; called by muse, mutect2, varscan2
- RUNDC1 | c.896G>A p.C299Y | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV64512383; called by muse, mutect2, varscan2
- SACS | c.12454G>A p.E4152K | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV66544925; called by muse, mutect2, varscan2
- SBNO1 | c.1229C>T p.S410F (on ENST00000420886; = p.S409F on NM_018183.5) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV57344427; called by muse, mutect2, varscan2
- SCARB2 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.61); catalogued as COSV53669944; called by muse, mutect2, varscan2
- SCRIB | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV57590235, COSV57591412; called by muse, mutect2, varscan2
- SCRN3 | c.942T>G p.F314L | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55809250; called by muse, mutect2, varscan2
- SDCBP2 | c.508C>T p.Q170* (on ENST00000339987 / NM_001199784.1; = p.Q85* on NM_015685.5) | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as COSV60589267; called by muse, mutect2, varscan2
- SDCCAG8 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV59414555; called by muse, mutect2, varscan2
- SDK1 | c.3371A>G p.E1124G | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.24); PolyPhen benign (0.428); catalogued as COSV67382695; called by muse, mutect2, varscan2
- SEC16A | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 31/52 reads (60%) | catalogued as rs1353045570, COSV99259737; called by muse, mutect2, varscan2
- SEMA5B | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV52104913; called by muse, mutect2, varscan2
- SEMA5B | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52104937; called by muse, mutect2, varscan2
- SEPTIN4 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57898365; called by muse, mutect2, varscan2
- SERBP1 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.055); catalogued as rs1347968911, COSV63414062; called by muse, mutect2, varscan2
- SETX | c.3976A>C p.T1326P | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56391637; called by muse, mutect2, varscan2
- SEZ6 | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760461187, COSV57983685; called by muse, mutect2, varscan2
- SEZ6L | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 203/230 reads (88%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV50657709, COSV50657985; called by muse, mutect2, varscan2
- SH3PXD2B | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61124843; called by muse, mutect2, varscan2
- SH3RF1 | c.137A>C p.E46A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52923705; called by muse, mutect2, varscan2
- SHANK1 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53258368; called by muse, mutect2, varscan2
- SHCBP1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57649488; called by muse, mutect2, varscan2
- SHOC1 | c.4018G>A p.E1340K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as COSV59505732; called by muse, mutect2, varscan2
- SIMC1 | c.455G>T p.S152I (on ENST00000443967 / NM_001308196.1; = p.S171I on NM_001308195.2) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100365799; called by muse, mutect2, varscan2
- SIRT1 | c.1826A>C p.E609A | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV53019633; called by muse, mutect2, varscan2
- SLC17A2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 99/170 reads (58%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV55352734, COSV55354204; called by muse, mutect2, varscan2
- SLC25A12 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55535572, COSV99785373; called by muse, mutect2, varscan2
- SLC26A8 | c.1651C>A p.P551T | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV62887107; called by muse, mutect2, varscan2
- SLC36A3 | c.422T>A p.L141* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | catalogued as COSV100077776; called by muse, mutect2, varscan2
- SLC38A10 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV55848108; called by muse, mutect2, varscan2
- SLC38A2 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV56746019; called by muse, mutect2, varscan2
- SLC39A10 | c.2356G>A p.G786S | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.376); catalogued as COSV56778411; called by muse, mutect2, varscan2
- SLC41A1 | c.755A>C p.N252T | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65651109; called by muse, mutect2, varscan2
- SLC46A2 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV65290303; called by muse, mutect2, varscan2
- SLC4A7 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV55398660, COSV99840154; called by muse, mutect2, varscan2
- SLC66A2 | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100673854; called by muse, mutect2, varscan2
- SLC6A2 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs963288063, COSV54913274; called by muse, mutect2, varscan2
- SLC8A2 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1236975349, COSV52641960; called by muse, mutect2, varscan2
- SLC8B1 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as rs777927547, COSV52529861; called by muse, mutect2, varscan2
- SLC9A8 | c.1120_1121del p.P374Sfs*4 | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | catalogued as COSV64290210; called by mutect2, pindel, varscan2
- SLCO6A1 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs372939815; called by muse, mutect2, varscan2
- SLF2 | c.1823T>C p.L608S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV53277510; called by muse, mutect2, varscan2
- SMC6 | c.3239G>A p.R1080K | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV61177218; called by muse, mutect2, varscan2
- SMYD1 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV70225716; called by muse, mutect2, varscan2
- SNRPE | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV65843388; called by muse, mutect2, varscan2
- SNX16 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 98/151 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100629709, COSV62036237; called by muse, mutect2, varscan2
- SNX33 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57914250; called by muse, mutect2, varscan2
- SOGA3 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1357538676, COSV64108059; called by muse, mutect2, varscan2
- SORBS1 | c.1358A>G p.E453G | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53362766; called by muse, mutect2, varscan2
- SORCS3 | c.2471T>C p.L824P | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100863733; called by muse, mutect2
- SORT1 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56668735; called by muse, mutect2, varscan2
- SORT1 | c.1439C>G p.S480* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV56668441, COSV99861022; called by muse, mutect2, varscan2
- SOX2 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100327273; called by muse, mutect2
- SOX5 | c.1898G>A p.C633Y | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58641997; called by muse, mutect2, varscan2
- SP1 | c.206G>A p.S69N (on ENST00000327443 / NM_138473.3; = p.S62N on NM_003109.1) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59404703; called by muse, mutect2, varscan2
- SPAG5 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); catalogued as COSV58803524; called by muse, mutect2, varscan2
- SPATS1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as COSV55824372; called by muse, mutect2
- SPEN | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV65366020; called by muse, mutect2, varscan2
- SPNS1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1292843126, COSV100209210; called by muse, mutect2, varscan2
- SPTLC1 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV52765823; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | PolyPhen probably damaging (0.998); catalogued as rs372411661, COSV50077837, COSV50078143; called by muse, mutect2, varscan2
- STRA6 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.385); catalogued as rs756324251, COSV60587815; called by muse, mutect2, varscan2
- STXBP5 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as COSV51656085; called by muse, mutect2, varscan2
- SUGP1 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV55923257; called by muse, varscan2
- SULT6B1 | c.608A>T p.Y203F (on ENST00000535679 / NM_001367551.1; = p.Y165F on NM_001032377.2) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.396); catalogued as rs1278847030, COSV53195688; called by muse, mutect2, varscan2
- SYNE1 | c.20587G>T p.G6863* (on ENST00000367255 / NM_182961.4; = p.G6792* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as COSV99574059; called by muse, mutect2, varscan2
- TAF1C | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs1487153657, COSV58987738; called by muse, mutect2, varscan2
- TAF3 | c.1864G>C p.D622H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV60209913; called by muse, mutect2, varscan2
- TAF3 | c.2145G>C p.E715D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.978); catalogued as COSV60209923; called by muse, mutect2, varscan2
- TAF7L | c.322C>T p.L108= | Splice Region (SNP) | VAF 46/55 reads (84%) | catalogued as COSV61256280, COSV61257754; called by muse, mutect2, varscan2
- TARBP1 | c.905G>A p.C302Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV50197861; called by mutect2, varscan2
- TARS2 | c.2115G>T p.E705D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV60874327; called by muse, mutect2, varscan2
- TAX1BP1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs1340986407, COSV55295605; called by muse, mutect2, varscan2
- TBC1D15 | c.1095G>C p.W365C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59851714; called by muse, mutect2, varscan2
- TBC1D2 | c.2197T>A p.F733I | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59787550; called by muse, mutect2, varscan2
- TBCD | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100833597, COSV100833601; called by muse, mutect2, varscan2
- TBL1XR1 | c.1183T>G p.Y395D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70499467, COSV70501617; called by muse, mutect2, varscan2
- TBPL1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV52784429; called by muse, mutect2, varscan2
- TBX3 | c.767G>A p.R256K (on ENST00000257566 / NM_016569.4; = p.R236K on NM_005996.4) | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as rs1372907987, COSV57474252; called by muse, mutect2, varscan2
- TBX4 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as COSV53609019; called by muse, mutect2, varscan2
- TCERG1 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.584); catalogued as rs1315193293, COSV57040311; called by muse, mutect2, varscan2
- TCHH | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); catalogued as COSV64276866; called by muse, mutect2, varscan2
- TCP11L2 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs747466761, COSV54431778; called by muse, mutect2, varscan2
- TDG | c.110A>C p.E37A | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV57167962; called by muse, mutect2, varscan2
- TENT4A | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50098413; called by muse, mutect2, varscan2
- TEPP | c.114T>G p.Y38* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV99333149; called by muse, mutect2, varscan2
- TEX15 | c.7034C>T p.T2345I (on ENST00000256246; = p.T2728I on NM_001350162.2) | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1292289601, COSV56351378; called by muse, mutect2, varscan2
- TFIP11 | c.2003C>G p.S668C | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.818); catalogued as COSV53227234; called by muse, mutect2
- TFRC | c.1677+1G>T p.X559_splice | Splice Site (SNP) | VAF 22/125 reads (18%) | catalogued as COSV64055928; called by muse, mutect2, varscan2
- THBS1 | c.640A>G p.N214D | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV52954658; called by muse, mutect2, varscan2
- THBS1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs761799391; called by muse, mutect2
- THOP1 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV57020185; called by muse, mutect2, varscan2
- THSD1 | c.2063G>A p.C688Y | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV51630611; called by muse, mutect2, varscan2
- TIMMDC1 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV51787567; called by muse, mutect2, varscan2
- TLL1 | c.2684C>G p.S895* | Nonsense Mutation (SNP) | VAF 54/108 reads (50%) | catalogued as COSV50304104, COSV99288506; called by muse, mutect2, varscan2
- TLL2 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV63574670; called by muse, mutect2, varscan2
- TLN1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV59210428; called by muse, mutect2, varscan2
- TLR5 | c.2161G>T p.D721Y | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV60560162; called by muse, mutect2
- TLR5 | c.2159G>C p.S720T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.637); catalogued as COSV60560168; called by muse, mutect2
- TMC4 | c.1411A>G p.K471E (on ENST00000617472 / NM_001145303.3; = p.K465E on NM_144686.4) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV55828354; called by muse, mutect2, varscan2
- TMEM169 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.2); PolyPhen benign (0.262); catalogued as COSV55266267; called by muse, mutect2, varscan2
- TMEM200C | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67309103; called by muse, mutect2, varscan2
- TMPRSS7 | c.1091-1G>A p.X364_splice (on ENST00000452346; = p.X238_splice on NM_001042575.2) | Splice Site (SNP) | VAF 43/181 reads (24%) | catalogued as rs1288514351, COSV69980558; called by muse, mutect2, varscan2
- TMTC2 | c.2070+2T>G p.X690_splice | Splice Site (SNP) | VAF 25/58 reads (43%) | catalogued as COSV58279066; called by muse, mutect2, varscan2
- TMTC3 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV57125568; called by muse, mutect2, varscan2
- TMTC3 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV57125576, COSV57125880; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV64102090; called by muse, mutect2, varscan2
- TNNI1 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60190173; called by muse, mutect2, varscan2
- TNNI2 | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV53290669, COSV99425369; called by muse, mutect2, varscan2
- TNXB | c.6740C>A p.P2247H (on ENST00000647633; = p.P2000H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV64485756; called by muse, mutect2, varscan2
- TOP1MT | c.1599G>C p.Q533H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV100239616; called by muse, mutect2
- TPRG1L | c.294G>A p.E98= | Splice Region (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100754762; called by muse, mutect2
- TRABD2A | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs935802556, COSV59104998; called by mutect2, varscan2
- TRHR | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV61235860; called by muse, mutect2, varscan2
- TRIM24 | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1447779351, COSV58976224; called by muse, mutect2, varscan2
- TRIM36 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV56692148; called by muse, mutect2, varscan2
- TRIM37 | c.567G>C p.M189I | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV51887330; called by muse, mutect2, varscan2
- TRIM47 | c.1435C>G p.R479G | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.225); catalogued as COSV54669169; called by muse, mutect2, varscan2
- TRIM49 | c.968C>A p.A323E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1319240638, COSV61670590; called by muse, mutect2, varscan2
- TRIM55 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as COSV52549447; called by muse, mutect2, varscan2
- TRIM8 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs745352731, COSV100192986, COSV56661598; called by muse, mutect2
- TRMT1L | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as rs1310224880, COSV100833475; called by muse, mutect2, varscan2
- TRPC7 | c.881A>G p.D294G | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1243141350, COSV61461643; called by muse, mutect2, varscan2
- TRPM4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs757286692, COSV53266966; called by muse, mutect2, varscan2
- TSPYL1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63994035, COSV63994239; called by muse, mutect2, varscan2
- TTC26 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 98/120 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV58273546; called by muse, mutect2, varscan2
- TTC7A | c.2567G>A p.R856K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as rs1029733941, COSV55413969; called by muse, mutect2, varscan2
- TTC7B | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1248228508, COSV60636339; called by muse, mutect2, varscan2
- TTN | c.89413G>A p.E29805K (on ENST00000591111; = p.E22381K on NM_003319.4) | Missense Mutation (SNP) | VAF 67/191 reads (35%) | PolyPhen probably damaging (0.994); catalogued as COSV60245939; called by muse, mutect2, varscan2
- TUBG2 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52219162; called by muse, mutect2, varscan2
- TXK | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 28/58 reads (48%) | catalogued as COSV99972702; called by muse, mutect2, varscan2
- TYR | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 27/53 reads (51%) | catalogued as rs1246720541, COSV99634954; called by muse, mutect2, varscan2
- UBAP2 | c.3005G>A p.G1002E | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214816886, COSV54291847; called by muse, mutect2, varscan2
- UBE2D3 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57661201, COSV57663600; called by muse, mutect2, varscan2
- UBE2N | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV58868762; called by muse, mutect2, varscan2
- UBE2Q2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV51195145; called by muse, mutect2, varscan2
- UBE2Q2 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51195251; called by muse, mutect2, varscan2
- UGT2B15 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1416709873, COSV100592410; called by muse, mutect2, varscan2
- UNC13C | c.899G>T p.R300M | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV52907500; called by muse, mutect2, varscan2
- UNG | c.382T>C p.Y128H (on ENST00000242576 / NM_080911.3; = p.Y119H on NM_003362.4) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54358295; called by muse, mutect2, varscan2
- UPF1 | c.1429C>T p.Q477* (on ENST00000599848 / NM_001297549.2; = p.Q466* on NM_002911.4) | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99440178; called by muse, mutect2, varscan2
- USB1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1303871646, COSV54623304; called by muse, mutect2
- USE1 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99812585; called by muse, mutect2, varscan2
- USP34 | c.8739G>A p.M2913I | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV68404509; called by muse, mutect2, varscan2
- USP34 | c.7020G>C p.Q2340H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV68399930, COSV68404514; called by muse, mutect2, varscan2
- UVSSA | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV66230609; called by muse, mutect2, varscan2
- VGLL3 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV67354041; called by muse, mutect2, varscan2
- VPS41 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 129/157 reads (82%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV59651765; called by muse, mutect2, varscan2
- VSIG10 | c.866A>C p.K289T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as COSV63654126; called by muse, mutect2, varscan2
- VSTM1 | c.320C>G p.S107* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100618877; called by muse, mutect2, varscan2
- VTCN1 | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60224568, COSV60224759; called by muse, mutect2, varscan2
- WAPL | c.3554A>C p.E1185A | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV53938663; called by muse, mutect2, varscan2
- WARS2 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as rs1010276895, COSV99346670; called by muse, mutect2, varscan2
- WASHC2A | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.807); catalogued as rs1203886825; called by mutect2, varscan2
- WDR25 | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58938875; called by muse, mutect2, varscan2
- WDR36 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs765795863, COSV72411386; called by muse, mutect2, varscan2
- WIF1 | c.1054G>C p.A352P | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.406); catalogued as COSV54134393; called by muse, mutect2, varscan2
- WNK1 | c.6311A>C p.K2104T (on ENST00000315939 / NM_018979.4; = p.K1856T on NM_014823.3) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV60041977; called by muse, mutect2, varscan2
- WNT10B | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV99976015; called by muse, mutect2, varscan2
- WRN | c.1166G>A p.R389K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV53304881; called by muse, mutect2, varscan2
- YIPF5 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV50823486; called by muse, mutect2, varscan2
- ZBED8 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.181); catalogued as COSV101283466, COSV68824947; called by muse, mutect2, varscan2
- ZBTB10 | c.1052_1072del p.L351_Q357del | In Frame Del (DEL) | VAF 50/98 reads (51%) | catalogued as COSV66948311; called by mutect2, pindel, varscan2
- ZBTB38 | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV58543572; called by muse, mutect2, varscan2
- ZC3H12C | c.1355G>C p.R452T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV53711430; called by muse, mutect2, varscan2
- ZCCHC3 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.583); catalogued as rs967100651, COSV66643648; called by muse, mutect2, varscan2
- ZDHHC22 | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60058790; called by muse, mutect2, varscan2
- ZEB2 | c.1636G>C p.D546H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57962979; called by muse, mutect2, varscan2
- ZFHX3 | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV51729545; called by muse, mutect2, varscan2
- ZHX2 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV58714608; called by muse, mutect2, varscan2
- ZMIZ1 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.933); catalogued as rs750935958, COSV57901313; called by muse, mutect2, varscan2
- ZNF18 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100503162; called by muse, mutect2
- ZNF234 | c.864C>G p.F288L | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV70603949; called by muse, mutect2, varscan2
- ZNF234 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV101468396; called by muse, mutect2, varscan2
- ZNF267 | c.130+1G>A p.X44_splice | Splice Site (SNP) | VAF 31/83 reads (37%) | catalogued as rs1261529838, COSV56255161; called by muse, mutect2, varscan2
- ZNF302 | c.634A>C p.T212P (on ENST00000627982; = p.T133P on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV71063827; called by muse, mutect2, varscan2
- ZNF318 | c.5312G>A p.R1771K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.107); catalogued as COSV58936033; called by muse, mutect2, varscan2
- ZNF431 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV60674686; called by muse, mutect2, varscan2
- ZNF519 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV101644750; called by muse, mutect2, varscan2
- ZNF567 | c.898C>T p.Q300* (on ENST00000536254 / NM_001322913.1; = p.Q269* on NM_152603.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100658930; called by muse, mutect2
- ZNF584 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1290876709, COSV59723064; called by muse, mutect2, varscan2
- ZNF623 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV71697305; called by muse, mutect2, varscan2
- ZNF710 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.993); catalogued as rs376006225; called by muse, mutect2, varscan2
- ZNF714 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1245437222, COSV52512897, COSV52514332; called by muse, mutect2, varscan2
- ZNF76 | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57354971; called by muse, mutect2, varscan2
- ZNF770 | c.1295A>G p.D432G | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62544739; called by muse, mutect2, varscan2
- ZNF784 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as rs575301558, COSV57596674; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 82/304 reads (27%) | catalogued as COSV100008374, COSV100008424; called by muse, mutect2, varscan2
- ZNF878 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.164); catalogued as rs751410013, COSV72156084; called by muse, mutect2, varscan2
- ZNF91 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV56090131; called by muse, mutect2, varscan2
- ZSWIM5 | c.3407G>A p.G1136E | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV55801605; called by muse, mutect2, varscan2
- ZWINT | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59186121; called by muse, mutect2, varscan2
- ARSJ | c.925_934del p.L309Rfs*45 | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | called by mutect2, pindel, varscan2
- ATP2C2 | c.363_387del p.A122Sfs*33 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- CCP110 | c.2064_2091del p.E689* | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- CD22 | c.1870_1881del p.V624_Y627del | In Frame Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- CEMIP | c.1460_1469del p.M487Rfs*5 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- DNAH9 | c.6890_6900del p.P2297Lfs*3 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- EEA1 | c.25-9_25-1delinsT p.X9_splice | Splice Site (DEL) | VAF 19/50 reads (38%) | called by pindel, varscan2*
- FBXO40 | c.613_633del p.K205_D211del | In Frame Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- FILIP1 | c.366del p.V123Cfs*17 | Frame Shift Del (DEL) | VAF 45/114 reads (39%) | called by mutect2, pindel, varscan2
- KCNJ15 | c.987_992dup p.F330_E331dup | In Frame Ins (INS) | VAF 27/99 reads (27%) | called by mutect2, varscan2
- KIF6 | c.1922dup p.Q642Tfs*10 | Frame Shift Ins (INS) | VAF 24/91 reads (26%) | called by mutect2, pindel, varscan2
- LARGE1 | c.1623_1642del p.Y541* | Nonsense Mutation (DEL) | VAF 7/73 reads (10%) | called by mutect2, pindel
- MRM1 | c.576C>G p.S192R | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH9 | c.3837+2T>C p.X1279_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2
- MYO18A | c.2827_2834del p.T943Afs*107 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- NEDD9 | c.-13_12+7del | Splice Site (DEL) | VAF 23/35 reads (66%) | called by mutect2, pindel
- NR2C1 | c.677_680del p.D226Vfs*10 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel, varscan2
- PAFAH1B3 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- PCDHGB5 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RESF1 | c.3898_3923del p.H1300* | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by mutect2, pindel
- SLC27A5 | c.1671_1687del p.W557Cfs*19 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- SLC30A1 | c.1106_1139del p.V369Afs*9 | Frame Shift Del (DEL) | VAF 39/106 reads (37%) | called by mutect2, pindel
- SNX19 | c.188_203del p.G63Afs*41 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- SRP72 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2
- TAF15 | c.316G>A p.D106N (on ENST00000605844 / NM_139215.3; = p.D103N on NM_003487.4) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TASOR2 | c.6538_6558del p.A2180_L2186del | In Frame Del (DEL) | VAF 18/51 reads (35%) | called by mutect2, pindel
- TMEM52B | c.479_518del p.P160Rfs*6 (on ENST00000381923 / NM_001079815.1; = p.P140Rfs*6 on NM_153022.4) | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel
- VAX2 | c.496del p.E166Rfs*38 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel*, varscan2
- ZNF548 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 11/342 reads (3%) | called by muse, mutect2
- ABCD1 | c.1092C>T p.A364= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as rs782250326, CD012236, COSV54386103, COSV54386996; called by muse, mutect2, varscan2
- ABCD4 | c.960C>T p.L320= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs1446557921, COSV53993733; called by muse, mutect2, varscan2
- ACADVL | c.1527G>A p.L509= | Silent (SNP) | VAF 25/34 reads (74%) | catalogued as COSV50038423; called by muse, mutect2, varscan2
- ACAN | c.7188C>T p.I2396= (on ENST00000560601 / NM_001369268.1; = p.I2320= on NM_001135.3) | Silent (SNP) | VAF 21/30 reads (70%) | catalogued as rs376206831; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACER1 | c.15C>T p.F5= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs866601862, COSV56836452; called by muse, varscan2
- AFAP1 | c.639G>A p.K213= | Silent (SNP) | VAF 114/211 reads (54%) | catalogued as COSV61797738; called by muse, mutect2, varscan2
- AFTPH | c.535C>T p.L179= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs1490525711, COSV53220646; called by muse, mutect2, varscan2
- AGAP1 | c.2361C>T p.L787= (on ENST00000304032 / NM_001037131.3; = p.L734= on NM_014914.5) | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV58335587; called by muse, mutect2, varscan2
- AKAP13 | c.2688T>C p.S896= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV63465784; called by muse, mutect2, varscan2
- AMBRA1 | c.219G>A p.V73= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV54060121; called by muse, mutect2, varscan2
- ANGPT4 | c.663G>A p.A221= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs1477326685, COSV67922454; called by muse, mutect2, varscan2
- ANKRD13C | c.102C>T p.L34= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV52030664; called by muse, mutect2, varscan2
- ANKRD26 | c.3165A>T p.L1055= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV65775428, COSV65777230; called by muse, mutect2, varscan2
- APC2 | c.531G>A p.S177= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1215802546, COSV99279716; called by muse, mutect2, varscan2
- ARFGEF2 | c.282C>T p.L94= | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as COSV64214219; called by muse, mutect2, varscan2
- ARL14 | c.477C>T p.L159= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV57900309; called by muse, mutect2, varscan2
- ATP10A | c.2028C>T p.N676= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV63521368; called by muse, mutect2, varscan2
- ATP1B3 | c.171G>A p.T57= | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as COSV53951093; called by muse, mutect2, varscan2
- B4GALNT3 | c.2721G>A p.V907= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV56756368; called by muse, mutect2, varscan2
- BAHCC1 | c.5715C>A p.I1905= | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, varscan2
- BCAR3 | c.2037C>T p.L679= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV53077830; called by muse, mutect2, varscan2
- BLOC1S4 | c.528G>A p.T176= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV57901276; called by muse, mutect2, varscan2
- BRK1 | c.45C>T p.D15= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- BTG1 | c.462C>T p.L154= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV55460088; called by muse, mutect2, varscan2
- BTN1A1 | c.306C>T p.I102= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV55067408; called by muse, varscan2
- BTN1A1 | c.348C>T p.V116= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV55066904, COSV55068934; called by muse, varscan2
- C6orf136 | c.909A>C p.S303= (on ENST00000376473 / NM_001109938.3; = p.S169= on NM_145029.4) | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV53315636; called by muse, mutect2, varscan2
- CAD | c.3432T>G p.G1144= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV53030412; called by muse, mutect2, varscan2
- CAMK2B | c.204G>A p.L68= | Silent (SNP) | VAF 66/78 reads (85%) | catalogued as COSV51664442; called by muse, mutect2, varscan2
- CARS1 | c.1917G>A p.V639= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as COSV53457552; called by muse, mutect2, varscan2
- CCER1 | c.888T>C p.D296= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as COSV62648120; called by muse, mutect2, varscan2
- CCR10 | c.820C>T p.L274= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs1163470423, COSV99226817; called by muse, mutect2, varscan2
- CD38 | c.105C>T p.L35= | Silent (SNP) | VAF 116/203 reads (57%) | catalogued as rs1329264471, COSV56892202; called by muse, mutect2, varscan2
- CDC23 | c.1473C>T p.I491= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV67510357; called by muse, mutect2, varscan2
- CDKAL1 | c.477G>A p.Q159= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as rs9465881, COSV51188092; called by muse, mutect2, varscan2
- CDON | c.2982G>A p.Q994= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV55000802; called by muse, mutect2, varscan2
- CDRT1 | c.1929C>T p.F643= | Silent (SNP) | VAF 87/248 reads (35%) | catalogued as COSV63053974; called by muse, mutect2, varscan2
- CELF4 | c.1347C>T p.F449= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs1213216912, COSV58450807; called by muse, mutect2, varscan2
- CEP170B | c.2637A>G p.P879= (on ENST00000453495; = p.P808= on NM_015005.3) | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV69025985; called by muse, mutect2, varscan2
- CEP350 | c.5502C>T p.I1834= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as COSV62607824; called by muse, mutect2, varscan2
- CFAP57 | c.87C>T p.I29= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs761394266, COSV52539366, COSV52541022; called by muse, mutect2, varscan2
- CHORDC1 | c.54C>G p.T18= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs138204033; called by muse, mutect2, varscan2
- CHST3 | c.156G>C p.L52= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV64151533; called by muse, mutect2, varscan2
- CIITA | c.1452C>T p.F484= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as rs1435094952, COSV60860578; called by muse, mutect2, varscan2
- CNTRL | c.5199G>A p.V1733= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV53051406; called by muse, mutect2, varscan2
- CORO6 | c.927C>T p.F309= | Silent (SNP) | VAF 67/140 reads (48%) | catalogued as COSV61471669; called by muse, mutect2, varscan2
- CRY2 | c.1227C>T p.F409= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV69889089; called by muse, mutect2, varscan2
- CTCF | c.477T>C p.P159= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV50497369; called by muse, mutect2, varscan2
- CTNND2 | c.492G>T p.G164= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs1410205497, COSV58912562; called by muse, mutect2, varscan2
- CTSH | c.441T>A p.T147= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV54986070; called by muse, mutect2, varscan2
- CYP2F1 | c.1410G>A p.L470= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV100462646, COSV58528510; called by muse, mutect2, varscan2
- DCAF13 | c.384T>G p.G128= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV52573554; called by muse, mutect2, varscan2
- DCST2 | c.627T>C p.C209= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV55053727; called by muse, mutect2, varscan2
- DDX28 | c.27C>T p.L9= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV60105755, COSV60106024; called by mutect2, varscan2
- DERA | c.78G>A p.L26= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV70775076; called by muse, mutect2, varscan2
- DHX15 | c.1272A>G p.A424= | Silent (SNP) | VAF 66/105 reads (63%) | catalogued as rs187424781; called by muse, mutect2, varscan2
- DMRT1 | c.1104C>T p.V368= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV66523388; called by muse, mutect2, varscan2
- DMXL2 | c.3636T>C p.A1212= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV51852470; called by muse, mutect2, varscan2
- DROSHA | c.849G>C p.R283= | Silent (SNP) | VAF 46/90 reads (51%) | catalogued as COSV100757410, COSV60780330; called by muse, mutect2, varscan2
- DUSP8 | c.90C>A p.I30= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs1303279750, COSV59029632, COSV59031004; called by muse, varscan2
- EHMT2 | c.2256C>T p.S752= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV64997479; called by muse, mutect2, varscan2
- ELF1 | c.654C>T p.L218= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV53501119, COSV53501504; called by muse, mutect2, varscan2
- ERBB2 | c.525G>A p.K175= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV54078129; called by muse, mutect2, varscan2
- ETV4 | c.195C>T p.L65= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV60045028; called by muse, mutect2, varscan2
- F5 | c.5382C>T p.L1794= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV63126539; called by muse, mutect2, varscan2
- FAM43B | c.60G>A p.A20= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs757258379, COSV60579971; called by muse, mutect2, varscan2
- FAM83H | c.2865G>A p.P955= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as rs565391047, COSV62029394; called by muse, mutect2, varscan2
- FANCF | c.309C>T p.L103= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV59416835; called by muse, mutect2, varscan2
- FGFR2 | c.936C>T p.L312= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV60655383; called by muse, mutect2, varscan2
- FKBP1A | c.273C>T p.I91= | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as COSV101098403; called by muse, mutect2, varscan2
- FMN2 | c.2361G>A p.L787= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs1180624926, COSV60445233; called by muse, mutect2, varscan2
- FMO3 | c.546C>T p.F182= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV63008157; called by muse, mutect2, varscan2
- FO393400.1 | c.345G>A p.Q115= | Silent (SNP) | VAF 55/68 reads (81%) | catalogued as COSV54069718, COSV54070793, COSV54071075; called by muse, mutect2, varscan2
- FOS | c.951C>A p.A317= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as rs1268786436, COSV57840134; called by muse, mutect2, varscan2
- FOXR2 | c.183G>A p.Q61= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as COSV59259258; called by muse, mutect2, varscan2
- GBP2 | c.906C>T p.I302= | Silent (SNP) | VAF 30/37 reads (81%) | catalogued as rs777876311, COSV65070071; called by muse, mutect2, varscan2
- GNA11 | c.288G>A p.T96= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV50017501; called by muse, varscan2
- GPAT3 | c.105C>G p.S35= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV52358820; called by muse, mutect2, varscan2
- GPBP1L1 | c.918C>T p.I306= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs765773919, COSV51967029; called by muse, mutect2, varscan2
- GPN2 | c.408C>T p.L136= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs754951334, COSV64652232; called by muse, mutect2, varscan2
- GRIN2D | c.504C>T p.T168= | Silent (SNP) | VAF 60/152 reads (39%) | catalogued as rs762242145, COSV54381331; called by muse, mutect2, varscan2
- GTF3C1 | c.1986G>A p.L662= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV62242452; called by muse, mutect2, varscan2
- HERC2 | c.6354C>T p.L2118= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV55341887; called by muse, mutect2, varscan2
- HGSNAT | c.1452T>C p.F484= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV52818344; called by muse, mutect2, varscan2
- HLX | c.1233C>T p.V411= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs760568441, COSV65045418; called by muse, mutect2, varscan2
- HOGA1 | c.216C>T p.F72= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs780606715, COSV65706601; ClinVar: likely benign; called by muse, mutect2, varscan2
- HOXB13 | c.441T>C p.S147= | Silent (SNP) | VAF 66/132 reads (50%) | catalogued as COSV51706869; called by muse, mutect2, varscan2
- HOXC6 | c.555C>T p.I185= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as COSV54537848; called by muse, mutect2, varscan2
- HSD11B1L | c.447G>A p.A149= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV56799356; called by muse, mutect2, varscan2
- IGSF10 | c.7335C>T p.I2445= | Silent (SNP) | VAF 61/129 reads (47%) | catalogued as COSV56390998; called by muse, mutect2, varscan2
- IL17D | c.540C>A p.I180= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs1200737868, COSV59231810; called by muse, mutect2, varscan2
189 further variants in this file (0 protein-altering or splice-affecting, 167 silent, 22 other) are not listed here.
